Somatic mutation profile of tumor specimen 0DRGF3 from CCDI case PBCGEI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.4 years (3,790 days).
Specimen 0DRGF3: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a2a8ed0-da99-4569-aa86-9f74e37e4b9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRIWE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00531a3a-a5e8-4873-94c5-8ed9b8dbd14f

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1, Translation Start Site 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FCGBP | c.7073C>T p.S2358L | Missense Mutation (SNP) | VAF 156/1853 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as rs772066429; called by muse, mutect2
- LAMA2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 67/537 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as CM981160; called by muse, mutect2, varscan2
- TTN | c.67003T>A p.F22335I (on ENST00000591111; = p.F14911I on NM_003319.4) | Missense Mutation (SNP) | VAF 88/575 reads (15%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OASL | c.1047+88A>T | Intron (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- PDCL2 | c.-47G>A | 5'UTR (SNP) | VAF 20/402 reads (5%) | catalogued as COSV99824016; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.*2G>T | 3'UTR (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
